Surgical pathology report (de-identified scan), TCGA case TCGA-56-8308, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8308-01A (Primary Tumor).

[page 1 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. - I.) LUNG, LEFT, UPPER LOBE, N10L (X2), N11L (X2), N9L, N7, N6, AND N5 LYMPH NODES, LOBECTOMY, WITH REGIONAL LYMPH NODE DISSECTION:
- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, TWO FOCI.
- LARGEST FOCUS:
- 4 cm in greatest dimension.
- Visceral pleural invasion: PRESENT.
- SECOND FOCUS:
- 1.9 cm in greatest dimension.
- Visceral pleural invasion: NOT IDENTIFIED.
- MARGIN STATUS: POSITIVE.
- Bronchial margin is positive for tumor.
- Vascular and parenchymal margins, negative for tumor.
- THIRTEEN LYMPH NODES, NEGATIVE FOR METASTASIS (0/13).
- SEE TUMOR STAGING SUMMARY BELOW.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Invasive squamous cell carcinoma, moderately differentiated.
Primary tumor: pT3 (two foci of tumor within the same lobe, 4 cm and 1.9 cm in greatest dimension).
Regional lymph nodes: pN0 (0/13 lymph nodes).
Distant metastasis: Not applicable.
Pathologic stage: IIB.
Lymphovascular invasion: Not identified.
Margin status: R1 (bronchial margin positive for invasive carcinoma).

Lung Tumor Staging Information

[page 2 of 5]
Procedure:	Lobectomy.
Specimen type:	Lung, upper lobe.
Specimen laterality:	Left.
Specimen integrity:	Intact.
Tumor Features:	
Tumor site:	Left lung, upper lobe.
Tumor size:	Largest focus: 4.2 cm in greatest dimension. Second focus: 1.9 cm in greatest dimension.
Tumor focality:	Multifocal.
Histologic type:	Squamous cell carcinoma.
Histologic grade:	Moderately differentiated (G2).
Lymphovascular invasion:	Not identified.
Perineural invasion:	Not identified.
Visceral pleural invasion:	Present, in association with the largest focus of tumor.
Tumor extension into extra-pulmonary structures:	Not identified.
Treatment effect:	Not applicable.
Lymph Nodes:	Thirteen lymph nodes, negative for metastasis (0/13).
Margin Evaluation:	POSITIVE (R1).
Distance to closest margin:	Tumor is present at the bronchial margin.
Bronchial margin:	POSITIVE for invasive carcinoma.
Vascular margin:	Uninvolved by invasive carcinoma.
Parenchymal margin:	Uninvolved by invasive carcinoma.
Parietal pleural margin:	Not applicable.
Chest wall margin:	Not applicable.
Other margins:	Not applicable.
Pathologic tumor staging descriptors:	
Primary tumor (pT):	pT3 (two foci of invasive carcinoma; 4.2 cm and 1.9 cm in greatest dimension).
Regional lymph nodes (pN):	pN0 (0/13 lymph nodes).
Distant metastasis (pM):	Not applicable.
Margin status (R):	R1 (bronchial margin positive for invasive carcinoma).
Pathologic stage:	IIB.
Additional pathologic findings:	Emphysematous changes, focal organizing pneumonia, respiratory bronchiolitis, focal heterotopic ossification.
Comment:	Not applicable.

[page 3 of 5]
Source of Specimen:

- A. N10L
- B. N11L
- C. N6
- D. Lung;LUL
- E. N11#2
- F. N9L
- G. N10L#2
- H. N7
- I. N5

Clinical History/Operative Dx:

Carcinoma left lung

Intraoperative Diagnosis:

D. Left upper lobe FS: Bronchial margin positive for squamous cell carcinoma. The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. The specimen is labeled and is received in formalin. It consists of two fragments of fibrofatty and focally anthracotic tissue varying from 0.7 - 0.9 cm in maximum dimension. The larger specimen is inked. Both specimens are serially sectioned and all tissue is submitted in cassette A1.

B. The specimen is labeled and is received in formalin. It consists of a single 1.9 x 1.4 x 0.9 cm fragment of dark red to anthracotic tissue. It is serially sectioned and entirely submitted in cassettes B1-B2.

C. The specimen is labeled and is received in formalin. It consists of a 4.5 x 1.8 x 1.3 cm strip of fibrofatty tissue. On dissection it contains a prominent anthracotic possible node measuring 2.2 x 1.4 x 1.1 cm. There are a few small specks of anthracotic discoloration within the remaining fibrofatty tissue. The possible node is serially sectioned and entirely submitted in cassettes C1-C2. The remaining fibrofatty tissue is submitted in cassettes C3-C4.

D. The specimen is labeled left upper lobe and is received without fixative. It consists of a lobe of lung which weighs 248 grams. It measures 17.5 cm from superior to inferior, 8 cm from medial to lateral, and 5

[page 4 of 5]
FINAL SURGICAL PATHOLOGY REPORT

cm from anterior to posterior. The pleural surface varies from pale red to dark red and there is heavy anthracotic streaking along the anterior and lateral surface following the rib pattern. There is some stringy fibrous adhesions along the apical portion of the lung. There is palpable nodularity in the inferior-anterior edge of the lung which appears to extend superiorly into the hilum of the lung. At the hilum the bronchial margin is identified. It is removed as a thin shave, and there is a fibrin/tumor plug in the inferior segmental bronchus. The bronchial margin is submitted for frozen section. There are prominent peribronchial nodes which appear somewhat matted inferior at the hilum. The vascular margins are identified and removed. Serial sections of the medial lung just inferior to the bronchus reveal gray-tan ill-defined neoplasm which involves an area measuring 4 x 3 x 2.1 cm. It abuts the pleural surface focally and the pleural surface is inked blue. At the anterior-inferior edge of the lung there appears to be a second relatively well circumscribed firm tan-white tumor mass which abuts the pleural surface both anteriorly and posteriorly. This second tumor mass is 1.9 cm from superior to inferior. Sections of the lung elsewhere reveal a few small subpleural areas of nodularity which are less than 0.3 cm in maximum dimension. There is bronchiectasis/atelectasis of the lung inferior to the hilum. Representative sections are submitted. Representative tumor is obtained for research purposes. Section summary: D1) bronchial margin from frozen section, D2) vascular margins, D3) inferior segmental bronchus with tumor plug, D4) prominent peribronchial node, superior hilum, D5-D9) sections of inferior hilar tumor progressing from the hilum toward the inferior edge of the lobe, D10) smaller nodule at anterior-inferior edge of lobe, D11) subpleural nodularity inferior-lateral surface of lung, D12) representative sections apical lung, D13) central lung, D14) basilar lung.

E. The specimen is labeled [REDACTED] and is received in formalin. It consists of a 1.1 x 0.7 x 0.7 cm fragment of anthracotic tissue. It is serially sectioned and entirely submitted in cassette E1. [REDACTED]

F. The specimen is labeled [REDACTED] and is received in formalin. It consists of three fragments of fibrofatty and anthracotic tissue which vary from 1.7 - 2 cm in maximum dimension. On dissection five lymph nodes are recovered varying from 0.4 - 2 cm in maximum dimension. The two largest nodes are sectioned and submitted in cassette F1 (one inked). The remaining nodes are submitted in cassette F2. [REDACTED]

G. The specimen is labeled [REDACTED] and is received in formalin. It consists of two fragments of fibrofatty and anthracotic tissue which is 0.8 - 1.4 cm in maximum dimension. On dissection two lymph nodes are recovered which vary from 0.9 - 0.6 cm. The largest node is serially sectioned and submitted in cassette G1. The remaining node is sectioned and submitted in cassette G2. [REDACTED]

H. The specimen is labeled [REDACTED] and is received in formalin. It consists of a 1.7 x 0.9 x 0.6 cm fragment of fibrofatty and anthracotic tissue and three separate 0.4 - 0.7 cm fragments of anthracotic tissue. The larger specimen is serially sectioned and submitted in cassette H1. The smaller tissue is submitted intact in cassette H2. [REDACTED]

I. The specimen is labeled [REDACTED] and is received in formalin. It consists of two fragments of fibrofatty and anthracotic tissue varying from 1.1 - 1.3 cm in maximum dimension. The larger specimen is serially sectioned and submitted in cassette I1. The smaller specimen is serially sectioned and submitted in I2. [REDACTED]

Microscopic Description:

[page 5 of 5]
FINAL SURGICAL PATHOLOGY REPORT

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

E. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

F. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

G. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

H. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

I. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Source: NCI Genomic Data Commons file 3c82bfce-cf88-4407-a275-e7cabaf71be6 (TCGA-56-8308.2BDD49AE-3401-416B-8069-4E375C759287.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).